Somatic mutation profile of tumor specimen ASCProject_0073_T1_WES (aliquot ASCProject_0073_T1_WES_1) from CMI case ASCProject_0073, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 50.3 years (18,386 days).
Specimen ASCProject_0073_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10e6c6c7-9443-42b2-8b1b-9e9f581c660a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0073_SALIVA (Saliva), aliquot ASCProject_0073_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2def39fb-2283-4c7c-8cc3-7e67273deaea

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, In Frame Del 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB4 | c.2418C>G p.Y806* | Nonsense Mutation (SNP) | VAF 39/144 reads (27%) | catalogued as rs377702127; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs869025196; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2473G>T p.D825Y | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.978); catalogued as COSV52226816; called by muse, mutect2, varscan2
- ADGRL1 | c.902G>A p.R301H (on ENST00000340736 / NM_001008701.3; = p.R296H on NM_014921.5) | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201495192, COSV100529155; called by muse, mutect2, varscan2
- GRIN2B | c.4241C>T p.A1414V | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as rs751107971, COSV101662990; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYBPC1 | c.2077C>T p.R693C (on ENST00000550270 / NM_206820.2; = p.R718C on NM_002465.4) | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747861353; called by muse, mutect2, varscan2
- NRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 118/685 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54736435; called by muse, mutect2, varscan2
- PGC | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs369400208; called by muse, varscan2
- SPAG5 | c.2881G>T p.A961S | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.209); catalogued as COSV56885862; called by muse, mutect2, varscan2
- UNC119B | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs756097983; called by muse, mutect2, varscan2
- VARS1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 93/572 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs55786236, COSV63305174; called by muse, mutect2, varscan2
- ASPM | c.5581_5586del p.Y1861_K1862del | In Frame Del (DEL) | VAF 18/108 reads (17%) | called by pindel, varscan2
- ATP6V1B2 | c.951del p.P318Lfs*14 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- CPXCR1 | c.41A>T p.N14I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- LTN1 | c.3365G>A p.G1122D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLCG1 | c.2073C>G p.F691L | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THRAP3 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASPM | c.5592T>G p.L1864= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, varscan2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2, varscan2
- CYLC1 | c.1935G>A p.P645= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as rs375075510; called by muse, mutect2, varscan2
- ITGA11 | c.3522C>T p.R1174= | Silent (SNP) | VAF 61/411 reads (15%) | catalogued as rs766508147; called by muse, mutect2, varscan2
- LAMTOR1 | c.15C>T p.Y5= | Silent (SNP) | VAF 78/444 reads (18%) | catalogued as COSV53827012; called by muse, mutect2, varscan2
- PCLO | c.14142C>A p.L4714= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs765893436; called by mutect2, varscan2
- SERPINA6 | c.129C>T p.N43= | Silent (SNP) | VAF 36/349 reads (10%) | catalogued as rs749109208, COSV58584336; called by muse, mutect2, varscan2
- TENM1 | c.24C>T p.P8= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- ZNF628 | c.189C>T p.P63= | Silent (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27196135 A>G | 3'Flank (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- AL590867.2 | n.95G>A | RNA (SNP) | VAF 51/792 reads (6%) | catalogued as rs370015919; called by muse, mutect2
